Somatic mutation profile of tumor specimen 0E0KXT from CCDI case PBCVFZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0KXT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fcadf28-679d-4ce0-b64d-c2c3a4bc782a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0KYB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b02a699d-a2f0-4024-ac66-838c87200975

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, 3'UTR 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL4 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 34/718 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs560787141, COSV100879356, COSV66105839; called by muse, mutect2
- BIVM-ERCC5 | c.1343T>C p.I448T | Missense Mutation (SNP) | VAF 62/660 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.295); catalogued as rs374920600; called by muse, mutect2
- TULP1 | c.1562C>A p.P521Q | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100004457, COSV57693505; called by muse, mutect2
- AHNAK | c.9289G>A p.D3097N | Missense Mutation (SNP) | VAF 49/515 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCTD5 | c.533del p.G178Afs*65 | Frame Shift Del (DEL) | VAF 21/167 reads (13%) | called by mutect2, varscan2
- MGAT4A | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 235/749 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SCN4A | c.3613A>C p.N1205H | Missense Mutation (SNP) | VAF 15/271 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- SPTA1 | c.4727A>G p.E1576G | Missense Mutation (SNP) | VAF 288/1006 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.595); called by muse, mutect2
- CAMK1G | c.1113C>A p.T371= | Silent (SNP) | VAF 42/644 reads (7%) | catalogued as COSV50521545; called by muse, mutect2
- MYO5C | c.3990G>A p.V1330= | Silent (SNP) | VAF 77/535 reads (14%) | called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- RILPL1 | c.*46G>A | 3'UTR (SNP) | VAF 15/127 reads (12%) | catalogued as rs775648935; called by muse, mutect2, varscan2
